CCDI case PBCABJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fb0aacb5-0d06-468c-b673-fe65be048128

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.7 years (7,212 days).

Biospecimens (2 samples)
- Sample 0DN1AY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN1DE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
